Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6GR, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6GR-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Final Results

Final

CASE NUMBER:

DIAGNOSIS: Adrenal, right, "adrenalectomy": Pheochromocytoma with vascular invasion. See Note.

NOTE: Vascular invasion is a risk factor for malignancy.

CLINICAL INFORMATION: Allocate Order to Protocol:

Brief

Clinical History:

pheochromocytomas Specimen Taken For Protocol:

Yes

PROCEDURE: Pre-Operative Diagnosis: pheochromocytomas Post-Operative

Diagnosis:

pheochromocytomas Operative Findings: right adrenal

pheochromocytomas

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT

GROSS DESCRIPTION: One specimen is received fresh in a container labeled with the patient's name, medical record number, and further specified as "right adrenal gland". It consists of an adrenalectomy specimen measuring 7.5 x 5 x 2 cm, and weighing 44.6 grams. The specimen feels soft on palpation. The specimen is inked black and cut to reveal a red-tan semi-liquid center. A ring of yellow tissue with adrenal gland is identified at the periphery. Approximately 1 x 1 x 1 cm of tissue is procured for Dr. . The procurement

was performed by Dr. . In the Gross Room, the specimen matches the above description. A small portion of normal-appearing adrenal tissue is present measuring about 1 cm located at the superior pole of the tumor. There is a periadrenal fatty tissue.

There is a soft and very friable mass measuring about 3.5 x 3 x 2.5 cm. The yellowish tumor mass looks to be arising from the medulla of the adrenal. The specimen is serially sectioned and representative sections are submitted in cassettes A, B, E, G and I - tumor with adjacent normal tissue; C, F -tumor, and D - normal appearing adrenal tissue; H is normal appearing adrenal gland close to resection margin. No lymph node or secondary mass can be grossly noted in the periadrenal fat.

Gross description dictated by

No consultants

#

Requested By

Do not file in Medical Record

[page 2 of 2]
#

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file d3718fbe-f57a-491c-b4e3-db6f6dc8cd4b (TCGA-QR-A6GR.E002FD9A-5D62-498C-A293-97D864CC0A00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).